Gene-level copy-number profile of tumor specimen TCGA-19-4065-02A from TCGA case TCGA-19-4065, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.3 years (13,257 days).
Specimen TCGA-19-4065-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.49134e8f-ff8b-49e3-b24f-b4ba0d63fe8f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-4065-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8ee6f10-35ef-43ec-a40a-888620d51f32

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 1; copy number 2: 2,481; copy number 3: 5,177; copy number 4: 33,816; copy number 5: 1,788; copy number 6: 13,374; copy number 7: 82; copy number 8: 1,637; copy number 9: 1,644; copy number 10: 101; copy number 11: 2; copy number 13: 94; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-4065-02A-11D-2002-01): tumor purity 0.49, ploidy 2.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:105,099,473–105,100,098, 1 gene: RAB9BP1.
- chr9:21,106,543–21,240,005, 15 genes: IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14.
- chr9:21,638,285–22,455,740, 19 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,741 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:24,542,952–31,645,160, 61 genes, copy number 9–11 (broad region; genes not listed).
- chr9:60,914,407–110,806,558, 850 genes, copy number 9–14 (within-gene range 8–14) (broad region; genes not listed).
- chr9:112,040,783–130,237,303, 387 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr14:105,836,765–106,335,613, 94 genes, copy number 13 (broad region; genes not listed).
- chr15:19,878,555–28,685,264, 346 genes, copy number 9 (broad region; genes not listed).
- chr19:47,745,546–47,768,840, 3 genes, copy number 9: NOP53, SNORD23, NOP53-AS1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
